Somatic mutation profile of tumor specimen 0DPDI1 from CCDI case PBCDGP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.8 years (4,685 days).
Specimen 0DPDI1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50b0bb26-a251-4365-9c24-1ffefd99f082.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPDHB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e2d5d1a-4376-4269-b4eb-785913006463

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5532G>C p.K1844N | Missense Mutation (SNP) | VAF 42/1685 reads (2%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1360182417; called by muse, mutect2
- ACACB | c.2024G>C p.R675P | Missense Mutation (SNP) | VAF 343/1354 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- AOPEP | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 170/706 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 32/1334 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- HNF4A | c.342C>T p.Y114= | Silent (SNP) | VAF 103/898 reads (11%) | called by muse, mutect2, varscan2
- KCNU1 | c.1779A>G p.P593= | Silent (SNP) | VAF 46/1404 reads (3%) | called by muse, mutect2
- ROBO1 | c.2049C>T p.P683= | Silent (SNP) | VAF 70/2134 reads (3%) | called by muse, mutect2
- TYW5 | c.303+47C>A | Intron (SNP) | VAF 188/575 reads (33%) | called by muse, mutect2, varscan2
